Gene-level copy-number profile of tumor specimen TCGA-4Z-AA7W-01A from TCGA case TCGA-4Z-AA7W, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 55.9 years (20,424 days).
Specimen TCGA-4Z-AA7W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.66750064-ac39-4363-b541-466261b79528.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-4Z-AA7W-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b324e591-0546-48e9-a50d-079ea7e85132

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 143; copy number 1: 5,657; copy number 2: 25,160; copy number 3: 17,702; copy number 4: 10,058; copy number 5: 396; copy number 6: 455; copy number 7: 116; copy number 8: 101; copy number 9: 2; copy number 10: 21; copy number 11: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-4Z-AA7W-01A-11D-A390-01): tumor purity 0.32, ploidy 2.63, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 143 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–3): AL359922.1.
- chr9:21,929,457–22,824,213, 12 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.
- chr12:63,760,358–64,162,217, 10 genes (within-gene range 0–2): AC084357.1, RXYLT1, RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1, AC020611.2.
- chr14:21,887,857–22,559,037, 118 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,093 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,692,182–40,294,180, 26 genes, copy number 5 (within-gene range 3–5): PPIE, AL035404.1, RNU7-121P, BMP8B, OXCT2, BMP8B-AS1, AL033527.2, AL033527.1, AL033527.3, LINC02811, TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1, CAP1, PPT1, OAZ1P1, RLF, RNU6-1237P, TMCO2, AL050341.2, ZMPSTE24, AL050341.1.
- chr1:147,019,656–147,295,765, 13 genes, copy number 6 (within-gene range 3–6): AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15, CHD1L.
- chr1:147,319,110–147,320,224, 1 gene, copy number 6: AC242426.1.
- chr1:149,048,576–156,082,465, 393 genes, copy number 6 (broad region; genes not listed).
- chr1:156,893,698–157,074,703, 7 genes, copy number 6: PEAR1, LRRC71, ARHGEF11, MIR765, RN7SL612P, SMU1P1, KRT8P45.
- chr1:159,649,151–161,964,070, 122 genes, copy number 8–10 (broad region; genes not listed).
- chr2:94,195,806–110,473,075, 382 genes, copy number 5–7 (broad region; genes not listed).
- chr3:65,174,916–66,038,834, 7 genes, copy number 7–9 (within-gene range 2–9): LINC02040, MAGI1, AC121493.1, ILF2P1, RPL17P17, MAGI1-IT1, MAGI1-AS1.
- chr3:68,004,247–68,545,621, 1 gene, copy number 7 (within-gene range 2–7): TAFA1.
- chr3:68,500,613–69,123,032, 12 genes, copy number 7: AC104167.1, AC096922.1, PSMC1P1, TAFA4, RNA5SP135, EOGT, AC109587.1, TMF1, MIR3136, UBA3, ARL6IP5, LMOD3.
- chr7:79,335,780–85,186,855, 48 genes, copy number 7 (within-gene range 4–7): AC074024.1, AC004945.1, MAGI2-AS3, NUP35P2, RNA5SP234, AC073048.1, GNAI1, RNU6-849P, RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P, CD36, SNRPBP1, GNAT3, AC073850.1, SEMA3C, AC004972.1, AC005008.2, AC005008.1, AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF, CACNA2D1, CACNA2D1-AS1, MTHFD2P5, AC004006.1, PCLO, RNA5SP235, AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2, SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16.
- chr12:27,022,546–27,502,185, 10 genes, copy number 6 (within-gene range 4–6): MED21, AC092747.4, C12orf71, AC092747.3, AC092747.1, AC092747.2, STK38L, ARNTL2, ARNTL2-AS1, SMCO2.
- chr12:69,212,108–69,823,204, 20 genes, copy number 5 (within-gene range 2–5): AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP.
- chr12:71,125,085–71,835,396, 14 genes, copy number 5 (within-gene range 2–5): TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2.
- chr12:71,849,228–71,850,428, 1 gene, copy number 5: MRS2P2.
- chr12:74,537,835–74,545,430, 2 genes, copy number 6: ATXN7L3B, AC025257.1.
- chr19:36,259,540–36,998,700, 29 genes, copy number 6 (within-gene range 3–6): LINC00665, AC092296.2, ZFP14, AC092296.1, AC092296.4, ZFP82, AC092296.3, ZNF566, AC092295.2, CTBP2P7, ZNF260, AC092295.1, ZNF529, ZNF529-AS1, ZNF382, ZNF461, AC074138.1, LINC01534, ZNF567, ZNF850, AC020928.1, AC020928.2, ZNF790-AS1, ZNF790, ZNF345, Y_RNA, ZNF829, RPL31P61, ZNF568.
- chr20:42,072,752–43,189,970, 5 genes, copy number 7–11 (within-gene range 3–11): PTPRT, AL035666.1, AL031656.1, PTPRT-AS1, RN7SKP100.

Autosomal genes at a single copy (total copy number 1): 5,611. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
